Surgical pathology report (de-identified scan), TCGA case TCGA-IK-7675, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Christiana Healthcare, specimen TCGA-IK-7675-01A (Primary Tumor).

SPECIMEN

- A. Right frontal tumor
- B. Right frontal mass deeper than first specimen
- C. Right frontal tumor (study)
- D. Right frontal tumor

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right frontal temporal mass

FROZEN SECTION DIAGNOSIS

- A) Brain, right frontal tumor, biopsy: Glioma.
- B) Brain, right frontal mass, biopsy: Glioma.

GROSS DESCRIPTION

A. The specimen is received unfixed labeled "right frontal tumor" and consists of portions of white soft tissue measuring 1 x 0.5 x 0.3 cm. in aggregate. The specimen is submitted for frozen section diagnosis as requested.

B. The specimen is received unfixed labeled "right frontal mass deeper than first specimen" and consist of a piece of white and red soft tissue measuring 1.2 x 0.7 x 0.3 cm. The specimen is submitted for frozen section diagnosis as requested.

C. The specimen is received unfixed labeled "right frontal tumor study" and consists of a portion of white soft tissue measuring approximately 1 cm in greatest aggregate dimension. The entire specimen is taken for research purposes as requested.

D. The specimen is received in formalin labeled "right frontal tumor" and consists of multiple pieces of white and red soft tissue occupying approximately 4.5 mL in volume.

MICROSCOPIC DESCRIPTION

The tumor is a moderately cellular oligodendroglioma. Portions of the tumor comprise gemistocytic astrocytes. No necrosis or marked atypia is seen. Case reviewed with [REDACTED]. A paraffin block of tumor will be sent for 1p/19q LOH testing. FISH. An addendum will be issued to this report with the FISH result.

DIAGNOSIS

A, B, D. Brain, right frontal tumor, biopsy: Oligodendroglioma (WHO grade II).

Source: NCI Genomic Data Commons file 1724c4ed-1da9-4675-8786-79e69ef7bada (TCGA-IK-7675.BB5FC5DF-BC8D-4603-A924-C2CBE7CD2E7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).